Somatic mutation profile of tumor specimen MP2PRT-PAUEZG-TMP1-A (aliquot MP2PRT-PAUEZG-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUEZG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.3 years (3,040 days).
Specimen MP2PRT-PAUEZG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1b5881e-2799-4617-a7da-e9216161740e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUEZG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUEZG-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/286394b0-03de-496a-937b-052fe9012786

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4, Translation Start Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 22/382 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 271/370 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.5120G>A p.R1707H | Missense Mutation (SNP) | VAF 49/714 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371566475, CM137491; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- CSGALNACT1 | c.205C>G p.R69G | Missense Mutation (SNP) | VAF 261/544 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV59981293; called by muse, mutect2, varscan2
- FREM3 | c.1768G>A p.G590R | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV61679269; called by muse, mutect2
- NUFIP1 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV64790995; called by muse, mutect2, varscan2
- OR10G4 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 125/296 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.887); catalogued as rs772273087; called by muse, mutect2, varscan2
- PLEKHA6 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 113/294 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55338746; called by muse, mutect2, varscan2
- SASH1 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 206/486 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.042); catalogued as rs139081709; called by muse, mutect2, varscan2
- ZEB2 | c.3113A>G p.H1038R | Missense Mutation (SNP) | VAF 31/403 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57953045; called by muse, mutect2
- ACP6 | c.1117T>C p.F373L | Missense Mutation (SNP) | VAF 144/338 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- BBC3 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 125/282 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOT1L | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 30/528 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NTRK3 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 20/621 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2
- PCDH15 | c.1357A>T p.T453S | Missense Mutation (SNP) | VAF 138/311 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- USP25 | c.2227C>T p.Q743* | Nonsense Mutation (SNP) | VAF 190/442 reads (43%) | called by muse, mutect2, varscan2
- ADGRB1 | c.2211C>T p.N737= | Silent (SNP) | VAF 120/271 reads (44%) | catalogued as rs754990402, COSV60101391; called by muse, mutect2, varscan2
- DNAH5 | c.7476G>A p.A2492= | Silent (SNP) | VAF 58/888 reads (7%) | catalogued as rs778257130, COSV99454279; called by muse, mutect2
- LONP1 | c.2118G>A p.E706= | Silent (SNP) | VAF 133/350 reads (38%) | catalogued as COSV99052278; called by muse, mutect2, varscan2
- OR2J3 | c.204C>T p.N68= | Silent (SNP) | VAF 177/449 reads (39%) | catalogued as rs201161327, COSV101013642; called by muse, mutect2, varscan2
